Gene-level copy-number profile of tumor specimen TCGA-98-A539-01A from TCGA case TCGA-98-A539, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.2 years (23,098 days).
Specimen TCGA-98-A539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.47729702-3598-4a49-bef9-def1ad2e9f1c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-A539-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf82c8e0-b769-4b1a-9df6-f96ba4d45077

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,685; copy number 2: 31,012; copy number 3: 5,985; copy number 4: 761; copy number 5: 294; copy number 7: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-A539-01A-31D-A25M-01): tumor purity 0.3, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 371 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:30,799,471–36,304,924, 202 genes, copy number 5 (broad region; genes not listed).
- chr22:18,970,439–19,031,242, 1 gene, copy number 5 (within-gene range 3–5): DGCR5.
- chr22:19,014,353–21,744,108, 168 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
